Gene-level copy-number profile of specimen HCM-CSHL-0318-C18-85B from HCMI case HCM-CSHL-0318-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Tumor grade: G2.
Specimen HCM-CSHL-0318-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05467ac6-6828-4854-b88c-be345bb98fd0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0318-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/dd2b51f6-a378-4948-9338-dd71b0df9859

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 511; copy number 1: 896; copy number 2: 13,884; copy number 3: 34,750; copy number 4: 6,241; copy number 5: 2,251; copy number 6: 303; copy number 7: 3; copy number 11: 41.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:181,114,106–181,131,169, 2 genes: AC008620.2, OR2V1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 44 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,306,368–36,329,340, 1 gene, copy number 7 (within-gene range 2–7): SH3D21.
- chr1:37,154,761–38,214,806, 43 genes, copy number 7–11: AL353604.1, MIR4255, RNU6-636P, RNA5SP43, RPS29P6, LINC01137, ZC3H12A, MIR6732, MEAF6, MIR5581, SNIP1, FTH1P1, AL034379.1, DNALI1, GNL2, RSPO1, C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4, AL929472.2, INPP5B, SNORA63, RNU6-584P, Metazoa_SRP, SF3A3, RNU6-510P, FHL3, UTP11, POU3F1, MIR3659HG, AL139158.1, MIR3659, AL390839.2, LINC01343.

Autosomal genes at a single copy (total copy number 1): 478. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
